Somatic mutation profile of tumor specimen TCGA-E7-A6ME-01A (aliquot TCGA-E7-A6ME-01A-22D-A32B-08) from TCGA case TCGA-E7-A6ME, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,670 days).
Specimen TCGA-E7-A6ME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a557ddd8-0c4e-4af6-a7a1-2c9f8406542f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A6ME-10B (Blood Derived Normal), aliquot TCGA-E7-A6ME-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96ae8c68-2960-419f-9795-6f3ab16a5618

The open-access MAF lists 148 somatic variants for this specimen: 102 protein-altering or splice-affecting, 40 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 40, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 3, Splice Region 2, Splice Site 2, RNA 2, Intron 2, 3'UTR 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 39/105 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV52517787, COSV52518375; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ADCK2 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV50781063; called by mutect2, varscan2
- ADGRE3 | c.1835G>C p.W612S | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53729768; called by muse, mutect2, varscan2
- AHNAK | c.7866T>G p.I2622M | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV57210153; called by muse, mutect2, varscan2
- AIFM1 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54853982; called by muse, mutect2, varscan2
- ALK | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1365924896, COSV66563948; called by muse, mutect2, varscan2
- AMER3 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); catalogued as rs748066995, COSV58466049; called by muse, mutect2, varscan2
- ANO8 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212896037, COSV50175176; called by muse, mutect2, varscan2
- ATAD5 | c.2888A>G p.Y963C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58973502; called by muse, mutect2, varscan2
- ATP9B | c.2815G>C p.G939R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100304214, COSV56949248; called by muse, mutect2, varscan2
- B4GALT1 | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV65707834; called by muse, mutect2, varscan2
- CBLIF | c.773A>T p.K258M | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV57237960, COSV57238532; called by muse, mutect2, varscan2
- CHD3 | c.4436C>G p.P1479R | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57874010; called by muse, mutect2, varscan2
- COASY | c.1505A>G p.E502G | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV55898163; called by muse, mutect2, varscan2
- COL6A2 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV56002789, COSV56016341; called by muse, mutect2
- COLEC12 | c.1318A>G p.I440V | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as rs370515092; called by muse, mutect2, varscan2
- CPXM2 | c.1589T>C p.V530A | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV53859736; called by muse, mutect2, varscan2
- CRACDL | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV67407590, COSV67409395, COSV67410310; called by muse, mutect2, varscan2
- CRB1 | c.3698C>T p.T1233I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV66329438; called by muse, mutect2, varscan2
- CREBBP | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as COSV52119422; called by muse, mutect2, varscan2
- CSF2RB | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1431256083, COSV53256887; called by muse, mutect2, varscan2
- CSTL1 | c.70C>G p.H24D | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs756043510, COSV55678010; called by muse, mutect2, varscan2
- CUBN | c.2626-1G>C p.X876_splice | Splice Site (SNP) | VAF 35/78 reads (45%) | catalogued as COSV64713023; called by muse, mutect2, varscan2
- DOCK10 | c.1360A>G p.M454V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749855361, COSV51371125; called by muse, mutect2, varscan2
- DUS1L | c.1252C>G p.R418G | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV57648470, COSV57651371; called by muse, mutect2, varscan2
- EXO5 | c.1099C>G p.P367A | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.098); catalogued as COSV56415537; called by muse, mutect2, varscan2
- EXOSC10 | c.834G>A p.Q278= | Splice Region (SNP) | VAF 45/141 reads (32%) | catalogued as COSV58664835, COSV58665468; called by muse, mutect2, varscan2
- FAM71A | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV54235298, COSV54236674; called by muse, mutect2, varscan2
- FAM89A | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV64166043; called by muse, mutect2, varscan2
- FLG | c.6470C>T p.S2157L | Missense Mutation (SNP) | VAF 132/586 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs761306814, COSV64237796; called by muse, varscan2
- H4C4 | c.32_55del p.L11_R18del | In Frame Del (DEL) | VAF 16/65 reads (25%) | catalogued as rs774755862; called by mutect2, pindel, varscan2
- HLA-DRA | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs1194365938, COSV66622669; called by muse, mutect2, varscan2
- IDH3B | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.923); catalogued as COSV61389579; called by muse, mutect2, varscan2
- IGHV1-46 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT tolerated (0.93); PolyPhen benign (0.11); catalogued as rs1555524774; called by muse, mutect2, varscan2
- IL17RE | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV55967646, COSV55971788; called by muse, mutect2, varscan2
- IRS1 | c.1088C>A p.A363D | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV59335251; called by muse, mutect2, varscan2
- KCNH7 | c.729A>T p.Q243H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.525); catalogued as COSV59793125; called by muse, mutect2, varscan2
- KCNJ6 | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.32); catalogued as COSV55712309, COSV55714224; called by muse, mutect2, varscan2
- KCNK9 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755968312, COSV57280117; called by muse, mutect2, varscan2
- KCNT2 | c.476T>A p.L159* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV99656531; called by muse, mutect2, varscan2
- LMBRD2 | c.369-1G>T p.X123_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as COSV56949390; called by muse, mutect2, varscan2
- LRRCC1 | c.2680G>C p.E894Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV64483136; called by muse, mutect2, varscan2
- MAGEB1 | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.69); PolyPhen benign (0.131); catalogued as COSV66775608; called by muse, mutect2, varscan2
- MARCO | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as COSV59055470, COSV59059940; called by muse, varscan2
- MELK | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53198112; called by muse, mutect2, varscan2
- MKI67 | c.6424C>G p.Q2142E | Missense Mutation (SNP) | VAF 76/128 reads (59%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.503); catalogued as COSV64073797; called by muse, mutect2, varscan2
- MUC16 | c.30343G>C p.E10115Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV67458624; called by muse, mutect2, varscan2
- MYH13 | c.5734G>A p.E1912K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52825159; called by muse, mutect2
- MYH9 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 24/39 reads (62%) | catalogued as COSV99339770; called by muse, mutect2, varscan2
- NAA15 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV56717752; called by muse, mutect2, varscan2
- NAP1L1 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as rs1207919622, COSV53874101; called by muse, mutect2, varscan2
- NLRP12 | c.2306A>G p.N769S | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs762331289, COSV60745961; called by muse, mutect2, varscan2
- NOL4 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52344105, COSV52358792; called by muse, varscan2
- OR10Z1 | c.737C>G p.T246R | Missense Mutation (SNP) | VAF 133/236 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs767358853, COSV100778929, COSV63523961; called by muse, mutect2, varscan2
- OR2T34 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60900130; called by muse, mutect2, varscan2
- OR4M1 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 140/326 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60059457, COSV60060434; called by muse, mutect2, varscan2
- OR6N1 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58647943; called by muse, mutect2, varscan2
- PCDHGC3 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV52748765; called by muse, mutect2, varscan2
- PDE9A | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV52324638; called by muse, mutect2, varscan2
- PLCB1 | c.509C>G p.P170R | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV62046025; called by muse, mutect2, varscan2
- PLEC | c.536G>A p.R179H (on ENST00000322810 / NM_201380.4; = p.R69H on NM_000445.5) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs781949709, COSV59606225; called by muse, mutect2, varscan2
- POLR3B | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57277875; called by muse, mutect2, varscan2
- PTPRT | c.3368G>C p.R1123T | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61973832, COSV62011329; called by muse, mutect2, varscan2
- RAMP1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV54537807; called by muse, mutect2
- RB1 | c.1463_1464insT p.C489Vfs*4 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | catalogued as COSV57302694; called by mutect2, varscan2
- RFC2 | c.1015G>A p.G339S (on ENST00000055077 / NM_181471.3; = p.G305S on NM_002914.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV50016062; called by muse, mutect2, varscan2
- ROS1 | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63853716; called by muse, mutect2, varscan2
- SALL1 | c.2943C>G p.I981M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV51755878; called by muse, mutect2, varscan2
- SBF1 | c.2803C>G p.R935G | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62366953; called by muse, mutect2, varscan2
- SGCZ | c.234G>A p.V78= | Splice Region (SNP) | VAF 13/39 reads (33%) | catalogued as COSV66008639; called by muse, mutect2
- SIGLEC11 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.259); catalogued as COSV70221944; called by muse, mutect2, varscan2
- SLC25A13 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV55705737; called by muse, mutect2, varscan2
- SLC5A11 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61741051; called by muse, mutect2
- SLITRK2 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV59424533; called by muse, mutect2, varscan2
- SNAP23 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV51041280; called by muse, mutect2, varscan2
- SNTG1 | c.1321G>A p.G441S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756353406, COSV52436528; called by muse, mutect2, varscan2
- SP4 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as COSV56021956, COSV56022276; called by muse, mutect2, varscan2
- SPOCK3 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62722622; called by muse, mutect2, varscan2
- STAC | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56208990; called by muse, mutect2, varscan2
- STAG2 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 89/112 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54355722; called by muse, mutect2, varscan2
- STAMBP | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV59897239; called by muse, mutect2, varscan2
- SYNE1 | c.17467G>C p.G5823R (on ENST00000367255 / NM_182961.4; = p.G5752R on NM_033071.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54953630; called by muse, mutect2, varscan2
- TBC1D2 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs755332434, COSV59784219; called by muse, mutect2, varscan2
- TENM2 | c.2923G>A p.G975S (on ENST00000518659 / NM_001122679.2; = p.G743S on NM_001080428.3) | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69127495; called by muse, mutect2, varscan2
- TLN1 | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.054); catalogued as COSV59206401; called by muse, mutect2, varscan2
- TRIM56 | c.1680C>G p.S560R | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV60158200; called by muse, mutect2, varscan2
- TYRO3 | c.1801G>A p.V601I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV55482529; called by muse, mutect2, varscan2
- UGT3A1 | c.1097T>C p.F366S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV57097268; called by muse, mutect2, varscan2
- WDR70 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs569699002; called by muse, mutect2, varscan2
- WDR81 | c.5089C>A p.R1697S (on ENST00000409644 / NM_001163809.2; = p.R646S on NM_152348.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV58480786, COSV58488231; called by muse, mutect2, varscan2
- ZBTB22 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56468256; called by muse, mutect2, varscan2
- ZNF224 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as rs763079230, COSV61241842; called by muse, mutect2, varscan2
- ZNF440 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58370792; called by muse, mutect2, varscan2
- ZNF486 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV58718491; called by muse, mutect2, varscan2
- CAPZA2 | c.254del p.G85Efs*17 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | called by mutect2, pindel, varscan2
- FLT4 | c.3216dup p.S1073Qfs*12 | Frame Shift Ins (INS) | VAF 15/27 reads (56%) | called by mutect2, pindel, varscan2
- KDM6A | c.3184_3185del p.D1062* | Frame Shift Del (DEL) | VAF 23/35 reads (66%) | called by mutect2, pindel, varscan2
- KMT2D | c.5808del p.S1937Pfs*110 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- OR6K2 | c.706del p.R236Afs*21 | Frame Shift Del (DEL) | VAF 40/77 reads (52%) | called by mutect2, pindel, varscan2
- PPP1R18 | c.391del p.D131Ifs*14 | Frame Shift Del (DEL) | VAF 38/122 reads (31%) | called by pindel, varscan2
- SYT10 | c.508dup p.R170Pfs*19 | Frame Shift Ins (INS) | VAF 141/251 reads (56%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.3471C>A p.S1157= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV51404153, COSV51422539; called by muse, mutect2, varscan2
- AIM2 | c.390T>C p.H130= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV63699218; called by muse, mutect2, varscan2
- C6orf62 | c.255A>G p.L85= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV65290322; called by muse, mutect2, varscan2
- CENPF | c.6699C>G p.L2233= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as rs149273910; called by muse, mutect2, varscan2
- CSE1L | c.261C>T p.A87= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs756518336, COSV53701186; called by muse, mutect2, varscan2
- CTNNA2 | c.1339T>C p.L447= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV58145738; called by muse, mutect2, varscan2
- CYSLTR2 | c.804C>T p.T268= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as rs1479596248, COSV56165562, COSV56167343, COSV99935250; called by muse, mutect2, varscan2
- DACT1 | c.2430C>G p.V810= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV60020253; called by muse, mutect2, varscan2
- DNAJC7 | c.327G>A p.L109= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs782298122, COSV57268523; called by muse, mutect2, varscan2
- DTWD2 | c.432G>A p.R144= | Silent (SNP) | VAF 62/96 reads (65%) | catalogued as COSV58365941; called by muse, mutect2, varscan2
- FAM47A | c.1674G>C p.P558= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as COSV60493816, COSV60495716; called by muse, mutect2, varscan2
- GHR | c.1146C>T p.G382= | Silent (SNP) | VAF 55/123 reads (45%) | catalogued as rs533441671, COSV50109690, COSV50121383; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GLUL | c.135G>C p.R45= | Silent (SNP) | VAF 57/96 reads (59%) | catalogued as COSV59381952; called by muse, mutect2, varscan2
- GPC5 | c.276C>T p.S92= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV65590484; called by muse, mutect2, varscan2
- GPR42 | c.114C>A p.V38= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV71995017, COSV71995025; called by muse, mutect2, varscan2
- HDHD3 | c.189C>T p.Y63= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs368069792; called by muse, mutect2, varscan2
- HMCN1 | c.13824C>A p.T4608= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as rs1253417094, COSV54891519; called by muse, mutect2, varscan2
- IRX1 | c.447C>T p.H149= | Silent (SNP) | VAF 54/87 reads (62%) | catalogued as COSV57358867, COSV57363036; called by muse, mutect2, varscan2
- LYST | c.3156A>G p.L1052= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as COSV67705869; called by muse, mutect2, varscan2
- MST1R | c.912A>G p.P304= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as COSV56567277; called by muse, mutect2, varscan2
- MX1 | c.852G>A p.Q284= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV55818713; called by muse, varscan2
- MX1 | c.858C>A p.I286= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV55818722; called by muse, varscan2
- MYH9 | c.1629G>T p.V543= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV53384479; called by muse, mutect2, varscan2
- NAGA | c.678C>T p.L226= | Silent (SNP) | VAF 13/13 reads (100%) | catalogued as COSV67169864; called by muse, mutect2, varscan2
- OR51B4 | c.465C>T p.P155= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV66517095; called by muse, mutect2, varscan2
- OR6T1 | c.549C>T p.P183= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV58306394; called by muse, mutect2, varscan2
- OR8J3 | c.651T>C p.S217= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV56880137; called by muse, mutect2, varscan2
- PDE4DIP | c.3390G>A p.G1130= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs782418750, COSV57689433; called by mutect2, varscan2
- PKP2 | c.672C>A p.G224= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as COSV50728566; called by muse, mutect2, varscan2
- REST | c.2901A>G p.E967= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV58360128; called by muse, mutect2, varscan2
- RNPEP | c.828G>A p.K276= | Silent (SNP) | VAF 52/218 reads (24%) | catalogued as COSV55240305; called by muse, mutect2, varscan2
- RPGR | c.1128A>G p.E376= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as COSV58834059; called by muse, mutect2, varscan2
- RRM2B | c.543T>C p.S181= | Silent (SNP) | VAF 77/183 reads (42%) | catalogued as COSV52566352; called by muse, mutect2, varscan2
- SLITRK2 | c.621G>T p.G207= | Silent (SNP) | VAF 43/55 reads (78%) | catalogued as COSV100157428, COSV59424546; called by muse, mutect2, varscan2
- SMPD3 | c.861G>A p.G287= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1220712513, COSV54711496; called by muse, mutect2, varscan2
- SORBS3 | c.1008G>A p.R336= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV53552465; called by muse, mutect2, varscan2
- USH2A | c.10890A>G p.K3630= | Silent (SNP) | VAF 59/100 reads (59%) | catalogued as CD1411356, COSV56354283; called by muse, mutect2, varscan2
- VPS35L | c.1200G>A p.Q400= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV51980803; called by muse, mutect2, varscan2
- WFDC10B | c.219A>G p.L73= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as rs776251606, COSV57913713; called by muse, mutect2, varscan2
- ZIC1 | c.894C>A p.G298= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs1450544309, COSV51550562, COSV51552405; called by muse, mutect2, varscan2
- CACNA1C | c.1217+328G>A | Intron (SNP) | VAF 5/8 reads (63%) | catalogued as COSV100221889; called by muse, mutect2, varscan2
- CHCHD2P9 | n.150C>T | RNA (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- COLQ | c.*108A>G | 3'UTR (SNP) | VAF 111/247 reads (45%) | catalogued as COSV101082488; called by muse, mutect2, varscan2
- MIR371A | n.58T>G | RNA (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- OR5AU1 | c.-2G>A | 5'UTR (SNP) | VAF 21/67 reads (31%) | catalogued as COSV58615483; called by muse, mutect2, varscan2
- RPL21 | c.242+85A>G | Intron (SNP) | VAF 63/144 reads (44%) | catalogued as COSV99699295; called by muse, mutect2, varscan2
